Surgical pathology report (de-identified scan), TCGA case TCGA-12-1598, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Duke, specimen TCGA-12-1598-01A (Primary Tumor).

[page 1 of 2]
Patient: [REDACTED]

AP Surgical Pathology: Additional Info [REDACTED] Acc# [REDACTED]

Surg Path

12-1598

CLINICAL HISTORY:

Brain tumor. MRI: MR images were obtained for localization purposes and compared to diagnostic MRI dated [REDACTED]. Again seen is large irregular enhancing lesion within the right temporal parietal lobe with central non enhancement.

GROSS EXAMINATION:

A. "Brain tissue (AF1)", received fresh for frozen section. A 3.6 x 3 x 2 cm portion of yellow-brown soft tissue is received. A representative section is frozen as AF1, the frozen remnant submitted in A1. Serial sectioning demonstrates a yellow-tan cut surface. Additional representative sections are submitted in A2-6.

B. "Brain tissue", received fresh and placed in formalin. Received are two fragments of red-tan soft tissue, 2.3 x 1.2 x 0.5 cm in aggregate. Serial sectioning demonstrates a red-tan cut surface. Representative submitted in block B1, the remaining tissue is retained in formalin.

INTRA OPERATIVE CONSULTATION:

A. "Brain tissue": AF1- glioblastoma [REDACTED]

MICROSCOPIC EXAMINATION:

Microscopic examination shows brain infiltrated by a malignant astrocytic neoplasm that is densely cellular and pleomorphic with, mitotic activity, microvascular proliferation, and necrosis. Tumor is present within the subarachnoid space.

DIAGNOSIS:

A. "BRAIN TISSUE" (BIOPSY):

GLIOBLASTOMA (WHO GRADE IV).
TUMOR IS PRESENT WITHIN THE SUBARACHNOID SPACE.

B. "BRAIN TISSUE" (BIOPSY):

GLIOBLASTOMA (WHO GRADE IV).

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed: [REDACTED]

ADDENDUM 1:

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

FISH INTERPRETATION SUMMARY:

CHROMOSOME 7 CENTROMERE - POLYSOMY (82% OF TUMOR CELLS EXHIBIT POLYSOMY)

EGFR - AMPLIFICATION (97% OF TUMOR CELLS EXHIBIT AMPLIFICATION)

CHROMOSOME 10 CENTROMERE - CENTROMERE LOSS (70% OF TUMOR CELLS EXHIBIT LOSS)

[page 2 of 2]
PTEN - ALLELIC LOSS (73% OF TUMOR CELLS EXHIBIT LOSS)

4 OF 4 ABNORMAL MARKERS.

COMMENT: A MULTIVARIATE SURVIVAL ANALYSIS OF [REDACTED] PATIENTS WITH GLIOBLASTOMAS REVEALS THAT THE HAZARD OF SHORT SURVIVAL AMONG PATIENTS WITH 0-2 ABNORMAL MARKERS (OUT OF 4) WAS SIGNIFICANTLY LOWER THAN THAT FOUND WITH PATIENTS WITH 4 ABNORMAL MARKERS EVEN AFTER ADJUSTMENT FOR AGE EFFECT.

12-1598

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]
Electronically signed: [REDACTED]

ADDENDUM 2:

IMMUNOHISTOCHEMICAL LABELING INDEX OF TUMOR CELLS:

TISSUE TYPE: BRAIN TISSUE CONTAINING GLIOBLASTOMA (WHO GRADE IV; [REDACTED], BLOCK A5).

MGMT - NEGATIVE (20% OF TUMOR CELLS)

EGFR wt - POSITIVE (3+ IN 80% OF TUMOR CELLS)

EGFR vIII - POSITIVE (3+ IN 20% OF TUMOR CELLS)

PTEN - NEGATIVE (2-3+ IN 60% OF TUMOR CELLS)

pS6 - POSITIVE (2+ IN 60% OF TUMOR CELLS)

pAKT - NEGATIVE (2+ IN 10% OF TUMOR CELLS)

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]
Electronically signed: [REDACTED]

Performed by: [REDACTED]

Source: NCI Genomic Data Commons file ea22b4fc-ba63-48dc-925a-e14bf0ca5809 (TCGA-12-1598.C319DE13-7A4D-452E-BAEA-5A5F64E9ADE5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).